Somatic mutation profile of tumor specimen TCGA-EL-A3D0-01A (aliquot TCGA-EL-A3D0-01A-12D-A202-08) from TCGA case TCGA-EL-A3D0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 61.9 years (22,622 days).
Specimen TCGA-EL-A3D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57462279-638d-4046-ac6f-10a0844ccded.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3D0-10A (Blood Derived Normal), aliquot TCGA-EL-A3D0-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4ec0a40-5f38-45b7-abb8-c6323a3f5835

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA5 | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs762408419, COSV67015522; called by muse, mutect2, varscan2
- BEND6 | c.831T>A p.D277E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV66067834; called by muse, mutect2, varscan2
- CACTIN | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50266552; called by muse, mutect2, varscan2
- CAMKK2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 132/308 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200886794, COSV61212467; called by muse, mutect2, varscan2
- FBN3 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs765032668, COSV54452393, COSV54469359; called by muse, mutect2, varscan2
- GCN1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56102972; called by muse, mutect2
- LRRC56 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV54236687; called by muse, mutect2, varscan2
- MYO10 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV72562858; called by muse, mutect2, varscan2
- OR1J2 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV58943630; called by muse, mutect2, varscan2
- OR2T34 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs749133438, COSV100170323; called by muse, mutect2, varscan2
- SLC12A5 | c.681G>A p.L227= (on ENST00000454036 / NM_001134771.2; = p.L204= on NM_020708.5) | Splice Region (SNP) | VAF 3/46 reads (7%) | catalogued as COSV54787096; called by muse, mutect2
- UBXN2B | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68308500; called by muse, mutect2, varscan2
- ZNF318 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as rs866272609, COSV58929874; called by muse, mutect2, varscan2
- BCOR | c.3677dup p.D1226Efs*19 (on ENST00000378444 / NM_001123385.2; = p.D1192Efs*19 on NM_017745.6) | Frame Shift Ins (INS) | VAF 48/104 reads (46%) | called by mutect2, pindel, varscan2
- C1GALT1C1L | c.876G>A p.R292= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV56749203; called by muse, mutect2
- CARMIL3 | c.3834C>T p.P1278= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV53742282; called by muse, mutect2, varscan2
- CASP4 | c.42G>A p.L14= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs1265665647, COSV67744149; called by muse, mutect2, varscan2
- EHD2 | c.1611C>A p.R537= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs760416934, COSV54406516; called by muse, varscan2
- ENPP2 | c.69T>C p.N23= | Silent (SNP) | VAF 45/192 reads (23%) | catalogued as COSV50009802; called by muse, mutect2, varscan2
- GPR155 | c.921G>A p.V307= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV55037024; called by muse, mutect2
- AP000769.3 | chr11:65503658 del AAATA | 5'Flank (DEL) | VAF 6/48 reads (13%) | catalogued as rs764217042; called by pindel, varscan2
